CCDI case PBCSDJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/9a146f9a-9335-4fda-8dd0-68e993c7dac7

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 0.2 years (73 days).

Biospecimens (2 samples)
- Sample 0DY8KG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DY8KQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
